Somatic mutation profile of tumor specimen HCM-CSHL-0192-C25-01A (aliquot HCM-CSHL-0192-C25-01A-11D-A79M-36) from HCMI case HCM-CSHL-0192-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.7 years (24,739 days).
Specimen HCM-CSHL-0192-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e74fd775-a46f-4556-aa4c-71c624a6837d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0192-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0192-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fb5949c-7a08-4863-8449-b57841cce1b2

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 74/265 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSM2A | c.1381C>T p.R461W (on ENST00000219054; = p.R382W on NM_001308169.2) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775799143; called by muse, mutect2, varscan2
- BRCC3 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 109/183 reads (60%) | catalogued as rs782566613, COSV57464580; called by muse, mutect2, varscan2
- CARNS1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 141/448 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs762936950; called by muse, mutect2, varscan2
- CEL | c.1777G>C p.A593P (on ENST00000673714; = p.A590P on NM_001807.6) | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.029); catalogued as rs539532953, COSV60827171; called by muse, varscan2
- COL6A2 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 174/540 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201792591, COSV100154215, COSV56015166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP3 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 208/708 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs888271095; called by muse, mutect2, varscan2
- PCDHGA4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 152/543 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375047889; called by muse, mutect2, varscan2
- PDZD7 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 107/389 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776680703, COSV100931710; called by muse, mutect2, varscan2
- RASGRF2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1329580753, COSV54126312; called by muse, mutect2, varscan2
- SRRM4 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs114691929; called by muse, mutect2, varscan2
- CDKN2A | c.110_141del p.L37Pfs*72 | Frame Shift Del (DEL) | VAF 94/259 reads (36%) | called by mutect2, pindel, varscan2
- CNGB3 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CREBBP | c.6107C>A p.P2036H | Missense Mutation (SNP) | VAF 151/485 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CTDSPL | c.405A>C p.E135D (on ENST00000273179 / NM_001008392.2; = p.E124D on NM_005808.3) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DSCAML1 | c.4324+1G>A p.X1442_splice (on ENST00000321322; = p.X1382_splice on NM_020693.4) | Splice Site (SNP) | VAF 57/196 reads (29%) | called by muse, mutect2, varscan2
- DUSP14 | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 131/574 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GGTLC1 | c.74A>T p.Y25F | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2B | c.4250T>A p.L1417H | Missense Mutation (SNP) | VAF 190/678 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCORL | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LYAR | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 147/422 reads (35%) | called by muse, mutect2, varscan2
- MCM3 | c.1224G>T p.M408I (on ENST00000229854 / NM_001366374.2; = p.M398I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THAP11 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZFP36L2 | c.921del p.S308Rfs*153 | Frame Shift Del (DEL) | VAF 196/769 reads (25%) | called by mutect2, pindel, varscan2
- ZNF611 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRB2 | c.1173C>T p.R391= | Silent (SNP) | VAF 74/442 reads (17%) | catalogued as rs143130521; called by muse, mutect2, varscan2
- CTSG | c.660G>A p.S220= | Silent (SNP) | VAF 114/337 reads (34%) | catalogued as rs757296409, COSV53536044; called by muse, mutect2, varscan2
- FOXN1 | c.1605A>G p.S535= | Silent (SNP) | VAF 98/311 reads (32%) | called by muse, mutect2, varscan2
- HOXD3 | c.1152G>A p.S384= | Silent (SNP) | VAF 177/598 reads (30%) | called by muse, mutect2, varscan2
- ITGAL | c.123C>T p.A41= | Silent (SNP) | VAF 141/414 reads (34%) | catalogued as rs754606863; called by muse, mutect2, varscan2
- PCDHGA1 | c.2106C>T p.C702= | Silent (SNP) | VAF 183/614 reads (30%) | catalogued as rs752862628, COSV65295884; called by muse, mutect2, varscan2
- STIM2 | c.75G>A p.R25= | Silent (SNP) | VAF 195/483 reads (40%) | called by muse, mutect2, varscan2
- TRPC7 | c.660C>T p.N220= | Silent (SNP) | VAF 108/346 reads (31%) | catalogued as COSV61452104; called by muse, mutect2, varscan2
- TRPM2 | c.3462-1256G>T | Intron (SNP) | VAF 83/367 reads (23%) | called by muse, mutect2, varscan2
